Surgical pathology report (de-identified scan), TCGA case TCGA-36-2545, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-2545-01A (Primary Tumor).

[page 1 of 5]
gical Pathology Consultation Report

TCGA-36-2545

Case Number

Collect Date:

Receive Date:

Date Reported

Patient's Name:

MRN:

PHN:

DOB/Gender:

**Ordering
Physician:**

Final Diagnosis:

- A. Right ovary and fallopian tube, salpingoophorectomy:
- 1. High grade serous carcinoma, grade 3 of 3 (please see comment)
- 2. Tumor involves the right ovary (8 cm in size), the right tubal fimbria (4 cm in size)
- 3. Tumor is present on the ovarian surface
- 4. Positive for lymphovascular invasion
- 5. Paratubal cyst
- B. BIOPSY RIGHT PELVIC SIDEWALL: positive for high grade serous carcinoma
- C. BIOPSY RIGHT PELVIC SIDEWALL 2: positive for high grade serous carcinoma
- D. Left ovary and fallopian tube, salpingoophorectomy:
- 1. High grade serous carcinoma, grade 3 of 3
- 2. Tumor involves the left ovary, 11 cm cystic tumor
- 3. Tumor is focally present on the ovarian surface
- 4. Unremarkable left fallopian tube
- E. Uterus and cervix, hysterectomy:
- 1. Bening proliferative endometrium
- 2. Unremarkable cervix
- 3. Unremarkable cul-de-sac
- 4. Negative for malignancy

[page 2 of 5]
F. RIGHT PELVIC SIDEWALL PLUS UTEROSACRAL LIGAMENT: positive for high grade serous carcinoma

G. Omentum, omentectomy:

1. Benign fibrofatty tissue with fibrous adhesions
2. Negative for malignancy

H. Corresponding peritoneal cytology [REDACTED] positive for malignant cells

[REDACTED]

[REDACTED]

Final Diagnosis Comment:

Both the right and the left ovaries are involved by a predominantly cystic high grade serous carcinoma. There is a 4 cm solid nodule of serous carcinoma present at the fimbriated end of the right fallopian tube, tethered to the surface of the right ovary. Even though no in situ carcinoma is present in the right tubal epithelium, this finding raises the possibility of a tubal origin for the carcinoma. This in situation with the [REDACTED], the possibility of a BRCA1/BRCA2 germline mutation needs to be considered.

Clinical History as Provided by Submitting Physician:

[REDACTED]

Pelvic masses (bilateral)

- A. (R) ovary
- B. Biopsy (R) pelvic sidewall
- C. Biopsy (R) pelvic sidewall 2
- D. Left ovary and tube
- E. Uterus with cervix
- F. (R) pelvic sidewall and uterosacral ligament
- G. Omentum

Specimens Received:

[page 3 of 5]
A: right ovary
B: biopsy right pelvic sidewall
C: biopsy right pelvic side wall #2
D: left ovary + tube
E: uterus + cervix
F: right pelvic sidewall + utero-sacral ligament
G: omentum

Gross Description:

The specimen is received in seven containers each labelled with the patient's demographics.

Container A is labelled RIGHT OVARY and consists of an 8 cm collapsed, focally opened, cystic ovarian tumour with a 4 cm solid mass with multiple friable, nodular/papillary excrescences on the surface involving the fimbriated end of the fallopian tube. A 3 x 1.5 cm proximal non-dilated fallopian tube is present just proximal to the area of irregular, friable, papillary excrescences. The remaining ovarian surface is otherwise smooth. The external surface of this cystic ovarian mass, including the mass at the fimbriated end of the fallopian tube is inked in black. A portion of tumour is submitted for intraoperative assessment and this portion is now re-submitted in cassette A1.

The opened unilocular cyst shows presence of slightly irregular papillary excrescences in about 20% of the inner surface while the remaining inner surface is slightly granular appearing. No grossly apparent residual ovarian tissue is present. The bulk of the tumour appears to be on the surface of the ovary associated with the fimbria (the 4 cm solid portion) and has a focally friable white-tan cut surface. A 2 cm paratubal cyst is also present. Additional sections are submitted as follows:

A2-A4 -tumour on the surface of the ovary
A5 -tumour in relation to the residual fimbriated end of the fallopian tube
A6 -tumour in relation to the paratubal cyst
A7-A8 -intraovarian cystic tumour and cyst wall
A9 -proximal portion of the non-tumoral fallopian tube

Container B is labelled BIOPSY RIGHT PELVIC SIDEWALL and consists of multiple fragments of friable tan-white tumour with similar appearance of the tumour from container A. The specimen is submitted in toto in cassettes B1 and B2.

Container C is labelled BIOPSY RIGHT PELVIC SIDEWALL 2 and consists of four yellow-tan fragments of tissue, 0.5-1.2 cm in size. The specimen is submitted in toto in C1.

Container D is labelled LEFT OVARY AND TUBE and consists of a collapsed, previously opened, cystic ovarian mass, 11 x 9 x 2.5 cm in size, and a 4.5 x 0.6 cm fallopian tube. The surface of the ovary is predominantly smooth except for a few 0.7-1.5 cm in size areas of surface irregularity, some of which are associated with a

[page 4 of 5]
palpable underlying cortical tumor nodule that ranges from 2-2.5 cm in size. These areas of surface irregularities are inked in black. The adventitial surface of the fallopian tube and fimbriated end of the fallopian tube is unremarkable grossly. Opened surface of the cystic ovarian mass shows a multilocular cystic mass that is composed predominantly of two large locules and a few smaller hemorrhagic locules. The inner linings of these locules are predominantly smooth with focal granular appearance. The cut surface of the externally palpable nodule shows a white-tan solid tumour, 3 cm in maximal size. Sections are submitted as follows:

D1-D2 -tumour nodule with focal surface involvement

D3 -tumour nodule and the inner lining

D4-D5 -additional surface tumour nodule

D6 -additional section of tumour in relation to the inner cyst lining

D7-D8 -additional cyst lining

D9-D10 -the entire fallopian tube

Container E is labelled UTERUS PLUS CERVIX and consists of a 9.5 x 6.5 x 4.5 cm uterus inclusive of the cervix with a 3 x 3.5 cm diameter cervix. The exocervical mucosa shows focal erythema but is otherwise unremarkable. The parametrial margin shows normal appearing soft tissue and is inked in black. The serosal surface of the uterus including the posterior cul-de-sac region shows no evidence of tumour involvement.

Bisected uterus shows a 3 x 0.6 cm unremarkable endocervical canal and a 4.5 x 1.5 cm unremarkable endometrial cavity with an average endometrial thickness of 0.2 cm. Sectioned surface of the uterus shows unremarkable endomyometrium. Sections are submitted as follows:

E1 -cul-de-sac

E2-E3 -anterior cervix and endocervical canal and lower uterine segment (1 contiguous section)

E4-E5 -posterior cervix, endocervical canal and lower uterine segment (1 contiguous section)

E6-E7 -anterior and posterior endomyometrium

Container F is labelled RIGHT PELVIC SIDEWALL PLUS UTEROSACRAL LIGAMENT and consists of multiple tan-yellow hemorrhagic fragments of tissue aggregating to 3 x 2 x 0.8 cm, grossly highly suspicious for tumour. All the tissue fragments are submitted in toto in F1-F3.

Container G is labelled OMENTUM and consists of a 28 x 18 x 1 cm fragment of omentum. Multiple areas of fibrous adhesions are visible externally, but no discrete mass lesions are present externally. Sectioned surface shows no definite mass lesion. Sections are submitted in cassettes G1-G10.

[page 5 of 5]
Intraoperative Consultation:

FSA/1

Gross Description: 8 cm collapsed, partly opened cyst with an adjacent solid mass, 4 cm adherent to (or part of) the cyst. Fallopian tube painted red.

Provisional Diagnosis: Poorly differentiated carcinoma. ?Serous.

Source: NCI Genomic Data Commons file 18d46511-8bdb-4d4b-8015-19f3f1a30f4c (TCGA-36-2545.E8E6F050-7372-41F3-B198-72DDB241FB08.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).